Surgical pathology report (de-identified scan), TCGA case TCGA-EX-A8YF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of North Carolina, specimen TCGA-EX-A8YF-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Sentinel lymph node #1, right external iliac, removal

- Two lymph nodes, no tumor seen, based on H & E sections, with one node showing isolated tumor cells (itc) on immunostain for pancytokeratin only (AE1/AE3) (0/2 itc+)

B: Sentinel lymph node, right obturator, removal

- One lymph node, no tumor seen, based on evaluation of H & E slides (0/1)

- Immunostain for pancytokeratin (AE1/AE3) confirms, with a high background

C: Lymph node, presacral, regional resection

- Five minute lymph nodes, no tumor seen (0/5)

D: Lymph nodes, right pelvic, regional resection

- Ten lymph nodes, no tumor seen (0/10)

E: Lymph nodes, left pelvic, regional resection

- Fifteen lymph nodes, no tumor seen (0/15)

F: Lymph nodes, right periaortic, regional resection

- Four lymph nodes, no tumor seen (0/4)

G: Uterus, cervix, parametrium, bilateral tubes, robotically assisted radical hysterectomy and bilateral salpingectomy

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor site: Cervix, unifocal, involving the entire anterior half of the cervix

Tumor size (greatest dimension): 3.2 cm (combined measurement of slides G6 and G7)

Extent of invasion:

Depth: 1.2 cm

Horizontal extent: 3.2 cm

IED-03

Carcinoma, squamous cell NOS
8070/3

Site Cervix NOS
0539

4/1/14

[page 2 of 5]
Cervical wall thickness: 3.0 cm

Percent invasion: 40% (G6-G7)

Lymphovascular space invasion: Present

Parametrial soft tissue involvement: Absent

Vaginal cuff involvement: Absent

Surgical margins:

Invasive: Negative (0.6cm from 12 o'clock margin)

Intraepithelial: Negative

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 37

Additional pathologic findings: Uterine leiomyoma, right hydrosalpinx, unremarkable left fallopian tube

AJCC Pathologic Stage: pT2a1 pN0 (itc) pMX

Note: This staging information is based on the pathologic specimen and may be incomplete. A comprehensive review of all available clinical information is recommended to determine final staging.

Comment:

Immunostains for the pancytokeratin AE1/AE3 are performed on blocks A1, A2, and B1, per sentinel lymph node protocol, with the above findings, with a high contamination background.

Clinical History:

-year-old female with a clinical diagnosis of cervical cancer who presents for robotic radical hysterectomy.

Gross Description:

Received are seven appropriately labeled containers.

Container A is additionally labeled "right external iliac sentinel lymph node #1". It holds a 3.2 x 1.5 x 0.5 cm tan/pink lymph node candidate. The lymph node candidate

[page 3 of 5]
is serially sectioned at close intervals and submitted in blocks A1 and A2,

Container B is additionally labeled "right obturator sentinel lymph node". It holds a 1.5 x 0.4 x 0.4 cm lymph node which is bisected and submitted in block B1,

Container C is additionally labeled "presacral lymph node." It holds a 1.5 x 1.5 x 0.5 cm fragment of tan/pink fibrous tissue. No lymph node is palpated. Tissue is submitted in blocks C1-C2,

Container D is additionally labeled "right pelvic lymph nodes." It holds multiple fragments of yellow fibrofatty tissue, 3.5 x 3.5 x 2.2 cm in aggregate. Palpated within the tissue are multiple lymph nodes, the largest is 1.5 cm.

Block Summary:

D1 - one lymph node, bisected
D2-D6 - multiple lymph nodes, each cassette,

Container E is additionally labeled "left pelvic nodes." It holds a 4.5 x 2.5 x 2.5 cm aggregate of yellow fibrofatty tissue. Within the tissue there are multiple lymph node candidates, the largest is 3.0 cm.

Block Summary:

E1 - multiple lymph nodes
E2-E4 - one lymph node each, each is bisected
E5-E6 - one lymph node, bisected
E7-E11 - multiple lymph nodes and fat,

Container F is additionally labeled "right periaortic." It holds a 3.2 x 1.5 x 1.0 cm fragment of tan/pink fibrous tissue. No lymph nodes are palpated.

Block Summary:

F1-F2 - one piece of tissue, bisected
F3 - remaining tissue

Container G is additionally labeled "uterus, cervix, perimetrium, bilateral tubes".

Adnexa: Bilateral fallopian tubes are received attached.

[page 4 of 5]
Ovaries are not present.

Weight: 230 grams

Shape: Pear shaped

Dimensions:

height: 4 cm

anterior to posterior width: 5 cm

breadth at fundus: 6.4 cm

Serosa: Smooth, gray/tan and glistening. Anterior paracervical soft tissue is inked blue and posterior paracervical soft tissue is inked black.

Cervix:

ectocervix: The peripheral ectocervix is smooth white/tan and glistening and the vaginal cuff dimensions are 6.4 cm anterior to posterior x 5.2 cm right to left.

tumor dimensions: 4.6 cm in length, 3.7 cm in diameter, 1.4 cm in maximum thickness

location: involves the entire anterior external os and extends into the canal as well as onto the ectocervix.

endocervix: Trabecular yellow and glistening, well-demarcated from the tumor.

other features: The tumor is solid gritty and friable

Endomyometrium:

length of endometrial cavity: 3.6 cm

width of endometrial cavity at fundus: 2.5 cm

thickness of lining: Ranges from 0.2 to 0.4 cm

other findings: None

Myometrium

thickness of myometrial wall at deepest gross invasion: 2.5 cm

other findings or comments: Contains intramural nodules up to 1.6 cm in greatest dimension having homogeneous white whorled cut surfaces.

Adnexa:

Right fallopian tube:

dimensions: 6.9 x 0.5 cm

other findings: The fallopian tube is discontinuous, has a patent lumen on sectioning and a grossly unremarkable fimbriated end.

Left fallopian tube:

dimensions: 6.4 cm in length ranging in diameter from 0.4 to 0.8 cm

other findings: The fallopian tube is discontinuous, has a patent lumen on sectioning and a grossly unremarkable fimbriated end.

[page 5 of 5]
Vagina: The vaginal cuff is smooth, white and glistening.

Urinary bladder: N.A

Rectum: N/A

Digital photograph taken: No

Lymph nodes: Submitted separately

Tissue submitted for special investigations:

Block Summary:

- G1 - perpendicular margin of tumor to closest anterior ectocervical margin (12 o'clock)
- G2 - 12 to 3 o'clock ectocervical margin, en face
- G3 - 3 to 6 o'clock ectocervical margin, en face
- G4 - 6 to 9 o'clock ectocervical margin, en face
- G5 - 9 to 12 o'clock ectocervical margin, en face
- G6 - anterior ectocervix
- G7 - anterior ectocervix and canal (G6-G7, representative bisected section)
- G8 - anterior endocervical canal
- G9-G10 - anterior endomyometrium, full thickness bisected
- G11 - posterior ectocervix
- G12 - posterior endocervical canal
- G13-G14- posterior endomyometrium, full thickness bisected
- G15 - right fimbria bisected
- G16 - cross sections of right fallopian tube
- G17 - left fimbria, bisected
- G18 - representative cross sections of left fallopian tube
- G19-G25- right perimetrium, entirely submitted
- G26-G27- left perimetrium, entirely submitted

Case is (circled)		✓

Source: NCI Genomic Data Commons file 893b4995-3be7-4a2a-95d4-83f1da8b01d6 (TCGA-EX-A8YF.AD08339B-E984-4E09-A8BF-C9FFE92E83F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).